TCGA case TCGA-BR-A4QI — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8bb9cfd8-7012-41b1-8aa1-b6592b0c0d43

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Ukraine; Age at index: 70 years; Vital status: Dead; Days to death: 652 days (1.8 years); Cause of death: Cancer Related.

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.3; Tissue or organ of origin: Gastric antrum; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 71.0 years (25,928 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 652 days (1.8 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 10.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide + Fluorouracil; Days to treatment start: 383 days (1.0 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide + Fluorouracil; Days to treatment start: 383 days (1.0 years); Days to treatment end: 551 days (1.5 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Days to treatment start: 383 days (1.0 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Days to treatment start: 383 days (1.0 years); Days to treatment end: 551 days (1.5 years); Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Lymph node, NOS. Age at diagnosis: 72.0 years (26,311 days); Days to diagnosis: 383 days (1.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.
3. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Pancreas, NOS. Age at diagnosis: 72.0 years (26,311 days); Days to diagnosis: 383 days (1.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.

Follow-up (5 entries)
- Days to follow up: 15 days; Disease response: Tumor Free.
- Day 383 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pancreas, NOS; Days to progression: 383 days (1.0 years); Evidence of progression type: Convincing Image Source.
- Day 383 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 383 days (1.0 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 415 days (1.1 years); Disease response: With Tumor.
- Days to follow up: 652 days (1.8 years); Disease response: With Tumor.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BR-A4QI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 270 mg.
  Slide TCGA-BR-A4QI-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BR-A4QI-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BR-A4QI-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Antrum/Distal; Lymph nodes examined: Yes; Cancer procurement city: Kiev; History reflux disease indicator: No; Antireflux treatment: No; History barretts esophageal indicator: No; History hpylori infection indicator: No; Treatment outcome first course: Complete Remission/Response.
- Drug treatment 1: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Drug treatment 4: Pharmaceutical therapy drug name: 5-Fluorouracil; Treatment best response: Clinical Progressive Disease.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; New tumor event site other: Pancreas; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 1, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Follow-up form 1, New neoplasm event types: New tumor event type: Distant Metastasis.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response; Cause of death: Stomach Cancer.
- Follow-up form 3: Lost to follow-up: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; New tumor event site: Non-regional / Distant Lymph Nodes; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 652 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 652 days; disease-free interval: event (new tumor event after initially disease-free), 383 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 383 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BR-A4QI-01A-12D-A253-01): tumor purity 0.53, ploidy 3.05, whole-genome doublings 1.
